FM case AD6590 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/f37cd200-076f-4e47-8102-9bf98e959081

Female, 55.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the pelvic bones, sacrum, coccyx and associated joints. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
